Somatic mutation profile of tumor specimen TCGA-EM-A3FK-01A (aliquot TCGA-EM-A3FK-01A-11D-A21A-08) from TCGA case TCGA-EM-A3FK, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 30.1 years (10,992 days).
Specimen TCGA-EM-A3FK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cea6dde5-0558-46d4-93f7-f20782923bf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3FK-10A (Blood Derived Normal), aliquot TCGA-EM-A3FK-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72d82ec8-2322-4208-954e-86bc9edc7c68

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1942C>T p.R648C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1484564944, COSV50506874; called by muse, mutect2, varscan2
- PITPNA | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.721); catalogued as COSV57935968; called by muse, mutect2, varscan2
- TRPV2 | c.2183C>A p.A728E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV58429799; called by muse, mutect2, varscan2
- CES4A | c.708C>G p.A236= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs574058890, COSV58655140; called by muse, mutect2, varscan2
